Somatic mutation profile of tumor specimen TCGA-TS-A7P1-01A (aliquot TCGA-TS-A7P1-01A-41D-A39R-32) from TCGA case TCGA-TS-A7P1, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 52.5 years (19,191 days).
Specimen TCGA-TS-A7P1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00fa283c-6180-4d75-8640-a1a77ca41ab2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7P1-10A (Blood Derived Normal), aliquot TCGA-TS-A7P1-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/343e8a82-8ddb-431e-8007-2f4a16a5dd9e

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 3, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4582G>C p.D1528H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99685278, COSV99686719; called by muse, mutect2, varscan2
- CNTNAP4 | c.3754T>C p.F1252L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100269407; called by muse, mutect2
- FCRL5 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1051334871; called by muse, mutect2, varscan2
- MROH2B | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs773695331, COSV68183292; called by muse, mutect2, varscan2
- POLRMT | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1275994539; called by muse, mutect2, varscan2
- VRK1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs888762581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDTC1 | c.979G>A p.G327S (on ENST00000319394 / NM_001276252.2; = p.G326S on NM_015023.5) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as rs200381090; called by muse, mutect2, varscan2
- BAP1 | c.1931del p.A644Efs*11 | Frame Shift Del (DEL) | VAF 29/64 reads (45%) | called by mutect2, pindel, varscan2
- CCDC73 | c.1997A>G p.Q666R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CSMD3 | c.10906C>A p.L3636I (on ENST00000297405 / NM_001363185.1; = p.L3467I on NM_052900.3) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNMT3A | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- GJB6 | c.699T>A p.N233K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IGFALS | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH4 | c.3856_3865+22del p.X1286_splice | Splice Site (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel
- PLEKHG3 | c.595_604del p.V199Pfs*5 (on ENST00000394691; = p.V255Pfs*5 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 41/124 reads (33%) | called by mutect2, pindel, varscan2
- SDK1 | c.1735_1749del p.P579_H583del | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- TRANK1 | c.3017A>G p.Y1006C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ZNF780B | c.2095_2098del p.C699Rfs*38 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by pindel, varscan2
- CHRNA10 | c.585C>T p.D195= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- FER1L5 | c.4722G>C p.L1574= (on ENST00000623019; = p.L1547= on NM_001293083.2) | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- PSG7 | c.639A>G p.G213= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as rs1319002804; called by muse, mutect2, varscan2
- RP1 | c.2373A>G p.K791= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- SZT2 | c.6684C>T p.T2228= (on ENST00000634258 / NM_001365999.1; = p.T2171= on NM_015284.4) | Silent (SNP) | VAF 68/169 reads (40%) | called by muse, mutect2, varscan2
- TRIM46 | c.1596C>T p.H532= | Silent (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
